Somatic mutation profile of tumor specimen C3L-01976-01 (aliquot CPT0109500009) from CPTAC case C3L-01976, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.6 years (23,587 days).
Specimen C3L-01976-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ebd6ec6-8a71-4327-b348-d7c25b7af7e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01976-31 (Blood Derived Normal), aliquot CPT0108370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3a32301-872d-4290-bd9c-0570bf0ff212

The open-access MAF lists 80 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Frame Shift Del 8, Nonsense Mutation 6, RNA 2, Splice Site 2, Intron 2, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B2 | c.1920C>G p.Y640* (on ENST00000672630; = p.Y607* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as COSV59249539; called by muse, mutect2, varscan2
- CREBZF | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758332106, COSV52630774; called by muse, mutect2
- GASK1B | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56706075, COSV56707132; called by muse, mutect2, varscan2
- GATA5 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs112353780; called by muse, mutect2, varscan2
- GRM5 | c.3511G>C p.D1171H (on ENST00000305447 / NM_001143831.2; = p.D1139H on NM_000842.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59610286; called by muse, mutect2, varscan2
- HEXD | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs573942733, COSV60065109; called by muse, mutect2
- KLHL6 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755341184; called by muse, mutect2, varscan2
- KRTAP11-1 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV60094898; called by muse, mutect2
- MUC17 | c.7534G>A p.E2512K | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV60286401; called by muse, mutect2
- NAV3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs377223602; called by muse, mutect2, varscan2
- PLEKHH2 | c.2517T>A p.Y839* | Nonsense Mutation (SNP) | VAF 10/245 reads (4%) | catalogued as COSV56758812; called by muse, mutect2
- VHL | c.539_540insTA p.V181Tfs*22 | Frame Shift Ins (INS) | VAF 125/507 reads (25%) | catalogued as COSV56549614; called by mutect2, pindel, varscan2
- VNN1 | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770005428; called by muse, mutect2
- ADAM32 | c.261T>G p.Y87* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- AMD1 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP1B1 | c.1676T>C p.L559P | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- C10orf90 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- CALHM4 | c.904A>G p.N302D (on ENST00000368596 / NM_001366078.1; = p.N116D on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CCDC25 | c.69del p.K23Nfs*7 | Frame Shift Del (DEL) | VAF 21/231 reads (9%) | called by mutect2, pindel
- CFAP57 | c.2816A>T p.Q939L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- COPE | c.773T>A p.V258D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CWF19L1 | c.1021T>A p.L341M | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP21A2 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 25/640 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- CYP2D6 | c.169T>C p.C57R | Missense Mutation (SNP) | VAF 35/538 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2
- DPF2 | c.922del p.Q308Nfs*5 | Frame Shift Del (DEL) | VAF 18/192 reads (9%) | called by mutect2, pindel
- DTHD1 | c.892G>C p.V298L (on ENST00000456874; = p.V133L on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2
- ENTPD8 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ETV6 | c.416_417del p.S139Yfs*14 | Frame Shift Del (DEL) | VAF 48/284 reads (17%) | called by pindel, varscan2
- FCER2 | c.265T>A p.S89T | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.031); called by muse, mutect2
- FRYL | c.6608A>T p.Q2203L | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- GLG1 | c.147_150del p.F49Lfs*73 | Frame Shift Del (DEL) | VAF 71/348 reads (20%) | called by mutect2, pindel, varscan2
- HEATR1 | c.331_332del p.Q111Efs*16 | Frame Shift Del (DEL) | VAF 50/213 reads (23%) | called by pindel, varscan2
- HMBOX1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HMCN1 | c.4655A>C p.N1552T | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITIH6 | c.3879G>T p.W1293C | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH6 | c.3878G>A p.W1293* | Nonsense Mutation (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- LRP2 | c.3455G>T p.S1152I | Missense Mutation (SNP) | VAF 69/338 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MAMDC4 | c.2345T>A p.L782Q (on ENST00000445819; = p.L703Q on NM_206920.3) | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYCBP2 | c.968T>G p.V323G (on ENST00000357337; = p.V361G on NM_015057.5) | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NECAP1 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OVCH2 | c.983del p.P328Qfs*33 | Frame Shift Del (DEL) | VAF 57/318 reads (18%) | called by mutect2, pindel, varscan2
- PACS1 | c.1491-2A>T p.X497_splice | Splice Site (SNP) | VAF 59/272 reads (22%) | called by muse, mutect2, varscan2
- POGLUT1 | c.342del p.F114Lfs*5 | Frame Shift Del (DEL) | VAF 43/184 reads (23%) | called by mutect2, pindel, varscan2
- POU2AF1 | c.392_400del p.Y131_V134delinsL | In Frame Del (DEL) | VAF 51/282 reads (18%) | called by mutect2, pindel, varscan2
- POU6F2 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 94/453 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRQ | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- REV3L | c.1547T>C p.L516P | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- RTEL1 | c.877G>C p.G293R | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SLC49A4 | c.918T>G p.I306M | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); called by muse, mutect2
- SORBS3 | c.863A>C p.K288T | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SRCAP | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SYNE1 | c.3115A>G p.R1039G (on ENST00000367255 / NM_182961.4; = p.R1046G on NM_033071.3) | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- TAOK2 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 16/316 reads (5%) | called by muse, mutect2
- THADA | c.4439-3_4442del p.X1480_splice | Splice Site (DEL) | VAF 21/100 reads (21%) | called by mutect2, pindel
- TTN | c.92389G>A p.E30797K (on ENST00000591111; = p.E23373K on NM_003319.4) | Missense Mutation (SNP) | VAF 43/196 reads (22%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TXNDC16 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- VPS54 | c.2440T>A p.L814M | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF385C | c.616del p.A206Lfs*2 | Frame Shift Del (DEL) | VAF 56/245 reads (23%) | called by mutect2, pindel, varscan2
- ZSCAN1 | c.1132A>T p.R378* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- AP3M2 | c.612G>C p.G204= | Silent (SNP) | VAF 30/168 reads (18%) | called by muse, mutect2, varscan2
- ATP10A | c.108C>G p.G36= | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- CASC3 | c.2010C>A p.A670= | Silent (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- DENND4C | c.3339G>C p.S1113= (on ENST00000434457 / NM_001330640.2; = p.S1064= on NM_017925.7) | Silent (SNP) | VAF 77/318 reads (24%) | catalogued as COSV63008578; called by muse, mutect2, varscan2
- DSC1 | c.1965T>C p.V655= | Silent (SNP) | VAF 74/342 reads (22%) | called by muse, mutect2, varscan2
- EML1 | c.1090C>T p.L364= | Silent (SNP) | VAF 52/229 reads (23%) | called by muse, mutect2, varscan2
- EPAS1 | c.2589C>T p.L863= | Silent (SNP) | VAF 95/427 reads (22%) | called by muse, mutect2, varscan2
- KLB | c.1801C>T p.L601= | Silent (SNP) | VAF 55/278 reads (20%) | catalogued as COSV99962338; called by muse, mutect2, varscan2
- SEMA6D | c.2907C>T p.S969= (on ENST00000316364 / NM_153618.2; = p.S907= on NM_020858.2) | Silent (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
- SLC43A2 | c.573A>T p.A191= | Silent (SNP) | VAF 18/340 reads (5%) | called by muse, mutect2
- SPEG | c.171C>A p.G57= | Silent (SNP) | VAF 19/179 reads (11%) | called by muse, mutect2, varscan2
- TFEB | c.874C>T p.L292= | Silent (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2259T>C p.S753= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs749310229; called by muse, mutect2, varscan2
- AC105942.1 | n.1045G>A | RNA (SNP) | VAF 27/244 reads (11%) | catalogued as rs1484306124; called by muse, mutect2
- AL353804.7 | chrX:73851371 C>T | 3'Flank (SNP) | VAF 100/418 reads (24%) | called by muse, mutect2, varscan2
- CNTFR | c.*98A>T | 3'UTR (SNP) | VAF 73/289 reads (25%) | called by muse, mutect2, varscan2
- COPG1 | c.872-15T>C | Intron (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- HNF4A | c.*9_*41del | 3'UTR (DEL) | VAF 32/212 reads (15%) | called by mutect2, pindel
- L1CAM | c.3457+23C>T | Intron (SNP) | VAF 14/437 reads (3%) | catalogued as rs1356064284; called by muse, mutect2
- PLEKHG1 | c.-38C>T | 5'UTR (SNP) | VAF 55/197 reads (28%) | catalogued as rs760914118, COSV62050118; called by muse, mutect2, varscan2
- RFPL4AP1 | n.751C>T | RNA (SNP) | VAF 8/215 reads (4%) | called by muse, mutect2
